Somatic mutation profile of tumor specimen TCGA-04-1336-01A (aliquot TCGA-04-1336-01A-01W-0486-08) from TCGA case TCGA-04-1336, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.5 years (20,271 days).
Specimen TCGA-04-1336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfe2cc87-888e-4803-b387-93e3742183f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1336-11A (Solid Tissue Normal), aliquot TCGA-04-1336-11A-01W-0487-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65c590e8-fa1f-489c-9c95-63a0353346b7

The open-access MAF lists 70 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 46/115 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV52517787, COSV52518375; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 163/200 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 34/155 reads (22%) | catalogued as COSV51844910; called by muse, mutect2, varscan2
- ADAMTSL1 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52818040; called by muse, mutect2, varscan2
- ADGRG4 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 327/412 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs746435155, COSV54959465; called by muse, mutect2, varscan2
- AHNAK2 | c.10065C>A p.D3355E | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.198); catalogued as COSV100315542, COSV60914561; called by muse, mutect2, varscan2
- ALOX15B | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 63/67 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66479630; called by muse, mutect2, varscan2
- ALPK1 | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 76/84 reads (90%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV51586712; called by muse, mutect2, varscan2
- C11orf53 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 22/185 reads (12%) | catalogued as COSV99724648; called by muse, mutect2, varscan2
- CABS1 | c.1062G>C p.K354N | Missense Mutation (SNP) | VAF 127/257 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV56733886; called by muse, mutect2, varscan2
- CDH17 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 120/445 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.137); catalogued as COSV50331190; called by muse, mutect2, varscan2
- CPXM1 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 82/102 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV66045874; called by muse, mutect2, varscan2
- CUBN | c.5732G>C p.R1911T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV64718991; called by muse, mutect2, varscan2
- DENND2A | c.2284C>A p.L762M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52053266, COSV99327124; called by muse, mutect2, varscan2
- DPYS | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 92/452 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as rs745993895, COSV60910032; called by muse, mutect2, varscan2
- DSC2 | c.808A>T p.K270* | Nonsense Mutation (SNP) | VAF 57/138 reads (41%) | catalogued as COSV51866202; called by muse, mutect2, varscan2
- EPHB1 | c.675C>A p.C225* | Nonsense Mutation (SNP) | VAF 42/1720 reads (2%) | catalogued as COSV101212761, COSV67669891; called by muse, mutect2
- ERG | c.986C>T p.S329L (on ENST00000398919 / NM_001243428.1; = p.S305L on NM_004449.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55734295; called by muse, mutect2, varscan2
- ETAA1 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV55473725; called by muse, varscan2
- FCGBP | c.12385G>A p.V4129M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs749313850; called by muse, mutect2, varscan2
- GABPB1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 215/231 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV99589609; called by muse, mutect2, varscan2
- IQCC | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs560946593, COSV52209549; called by muse, mutect2, varscan2
- ITGA11 | c.3285A>C p.A1095= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100241040; called by muse, mutect2
- KIFC2 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs1251167801, COSV56761632; called by muse, mutect2, varscan2
- KRT6A | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV58105903; called by muse, mutect2, varscan2
- KRTAP13-3 | c.259A>C p.M87L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61879529; called by muse, mutect2, varscan2
- LAMB1 | c.3109C>A p.Q1037K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV55966451; called by muse, mutect2, varscan2
- LAMC1 | c.2505T>A p.D835E | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51148648; called by muse, mutect2, varscan2
- LNX2 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 148/176 reads (84%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV60336462; called by muse, mutect2, varscan2
- MAMSTR | c.1199C>T p.S400F (on ENST00000318083 / NM_001130915.2; = p.S297F on NM_182574.2) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.879); catalogued as COSV58881949; called by muse, mutect2, varscan2
- MLIP | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 464/1029 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778702684, COSV51431828; called by muse, mutect2, varscan2
- MTNR1A | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 101/120 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56156655; called by muse, mutect2, varscan2
- MYT1 | c.3310G>C p.E1104Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60508008; called by muse, mutect2, varscan2
- PAK2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 200/615 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV59082205; called by muse, mutect2, varscan2
- PCDHB9 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as rs1554282848, COSV53375004; called by muse, mutect2, varscan2
- PLD5 | c.848G>T p.W283L (on ENST00000442594; = p.W221L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV59151551; called by muse, mutect2, varscan2
- PRAMEF12 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 104/251 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as rs960570403, COSV63215722; called by muse, mutect2, varscan2
- PSKH2 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV52611026; called by muse, mutect2, varscan2
- PXK | c.202-1G>T p.X68_splice | Splice Site (SNP) | VAF 20/34 reads (59%) | catalogued as COSV57088001, COSV57089086; called by muse, mutect2, varscan2
- SEL1L2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99532705; called by muse, mutect2
- SLC12A3 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV52636236; called by muse, mutect2, varscan2
- SMG8 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV56285946; called by muse, mutect2, varscan2
- SYNGAP1 | c.2377A>T p.K793* | Nonsense Mutation (SNP) | VAF 137/405 reads (34%) | catalogued as rs1554122165, COSV53382704; called by muse, mutect2, varscan2
- TNRC6A | c.3065G>T p.W1022L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100169533; called by muse, mutect2, varscan2
- TNRC6A | c.3066G>T p.W1022C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59369171, COSV59369272; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1961T>A p.V654D | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV51956904; called by muse, mutect2, varscan2
- ZFHX3 | c.10294T>A p.S3432T | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV51723082; called by muse, varscan2
- ZFHX4 | c.4584T>A p.N1528K | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV51447303; called by muse, mutect2, varscan2
- ASTN1 | c.2229_2244del p.Q743Hfs*11 | Frame Shift Del (DEL) | VAF 116/445 reads (26%) | called by mutect2, pindel, varscan2
- CEACAM1 | c.959-18_959del p.X320_splice | Splice Site (DEL) | VAF 81/348 reads (23%) | called by mutect2, pindel, varscan2
- CSMD1 | c.7907_7911del p.G2636Vfs*56 (on ENST00000520002; = p.G2635Vfs*56 on NM_033225.6) | Frame Shift Del (DEL) | VAF 84/281 reads (30%) | called by pindel, varscan2
- FAM83E | c.1094G>C p.G365A | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.056); called by muse, mutect2
- MRC1 | c.1964G>C p.R655T | Missense Mutation (SNP) | VAF 120/311 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PITPNM1 | c.360dup p.Q121Afs*54 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- SFPQ | c.1592_1600del p.Q531_N533del | In Frame Del (DEL) | VAF 35/88 reads (40%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.1858_1867del p.S620Qfs*25 | Frame Shift Del (DEL) | VAF 71/149 reads (48%) | called by mutect2, pindel, varscan2
- SLC1A2 | c.1111_1117del p.T371Vfs*13 | Frame Shift Del (DEL) | VAF 130/429 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.1821T>C p.T607= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV67133752; called by muse, mutect2, varscan2
- AHNAK2 | c.8379G>A p.A2793= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs371203043; called by muse, mutect2, varscan2
- ATP10B | c.2133C>T p.A711= | Silent (SNP) | VAF 71/89 reads (80%) | catalogued as COSV59155711; called by muse, mutect2, varscan2
- CELA2A | c.585C>T p.S195= | Silent (SNP) | VAF 133/291 reads (46%) | catalogued as rs1002666141, COSV62747706; called by muse, mutect2, varscan2
- DLG5 | c.4015A>C p.R1339= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as COSV64948515; called by muse, mutect2, varscan2
- ELN | c.1617G>A p.Q539= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as COSV52711668; called by muse, mutect2, varscan2
- FLI1 | c.849G>A p.L283= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1179005819, COSV55645541; called by muse, mutect2, varscan2
- GABPB1 | c.183T>A p.G61= | Silent (SNP) | VAF 212/228 reads (93%) | catalogued as COSV99589606; called by muse, mutect2, varscan2
- HERC5 | c.1848T>C p.T616= | Silent (SNP) | VAF 76/86 reads (88%) | catalogued as COSV52041164; called by muse, mutect2, varscan2
- ILRUN | c.588G>T p.T196= (on ENST00000374023 / NM_024294.4; = p.T130= on NM_022758.6) | Silent (SNP) | VAF 84/209 reads (40%) | catalogued as COSV64990463; called by muse, mutect2, varscan2
- MAGI2 | c.1881G>C p.R627= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs989791806, COSV62671707; called by muse, mutect2, varscan2
- POU3F4 | c.1032G>A p.P344= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs41312552, COSV100937251, COSV64539573; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1335G>C p.G445= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV53453620; called by muse, mutect2, varscan2
